Gene-level copy-number profile of tumor specimen TCGA-D8-A1XQ-01A from TCGA case TCGA-D8-A1XQ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 69.4 years (25,345 days).
Specimen TCGA-D8-A1XQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.fd2ba09e-a9f8-4cda-810c-ac29afd0e6b2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A1XQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cb47aab8-3f47-4010-9b3c-7fcfb9161243

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,018; copy number 2: 7,822; copy number 3: 16,069; copy number 4: 16,674; copy number 5: 9,815; copy number 6: 3,339; copy number 7: 997; copy number 8: 1,220; copy number 9: 837; copy number 10: 781; copy number 11: 663; copy number 12: 82; copy number 14: 30; copy number 15: 335; copy number 22: 127.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A1XQ-01A-11D-A14J-01): tumor purity 0.48, ploidy 3.85, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,855 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–151,459,494, 316 genes, copy number 15 (broad region; genes not listed).
- chr3:127,480,690–128,408,646, 22 genes, copy number 9: LINC01471, AC016968.1, LINC02034, AC084035.1, TPRA1, MIR6825, MIR7976, MCM2, AC023593.1, PODXL2, ABTB1, MGLL, AC117480.1, KBTBD12, RNA5SP139, SEC61A1, RUVBL1, RNU2-37P, RUVBL1-AS1, RNU6-823P, EEFSEC, AL449214.1.
- chr3:168,858,659–198,222,513, 593 genes, copy number 10–12 (broad region; genes not listed).
- chr6:167,607–11,862,970, 235 genes, copy number 11–14 (broad region; genes not listed).
- chr6:37,005,646–38,154,624, 24 genes, copy number 10 (within-gene range 7–10): FGD2, COX6A1P2, RPL12P2, PIM1, TMEM217, AL353579.1, TBC1D22B, AL096712.1, AL096712.2, RNF8, RN7SL273P, CMTR1, CCDC167, LINC02520, AL353597.2, AL353597.1, MIR4462, AL353597.3, MDGA1, AL121574.1, ZFAND3, RN7SL285P, RNVU1-33, AL589655.1.
- chr6:38,207,274–38,207,345, 1 gene, copy number 10: AL033518.1.
- chr6:52,361,421–53,665,756, 50 genes, copy number 9 (within-gene range 7–9): PAQR8, EFHC1, TRAM2, TRAM2-AS1, AL109918.2, AL109918.1, TMEM14A, GSTA8P, SREK1IP1P2, GSTA7P, GSTA2, GSTA12P, GSTA1, GSTA6P, GSTA5, GSTA11P, GSTA10P, GSTA3, GSTA9P, AL121969.1, GSTA4, 7SK, RN7SK, CILK1, AL031178.1, FBXO9, AL031178.2, RN7SL244P, AL512347.1, GCM1, RNU6-464P, SOD1P1, AL512378.1, RNU1-136P, HMGB1P20, ELOVL5, MIR5685, RPS16P5, AL034374.1, RPL31P28, RPL31P33, RPA3P2, AL591034.1, RN7SKP256, NANOGP3, GCLC, AL033397.2, AL033397.1, LINC01564, KLHL31.
- chr6:55,939,790–74,690,727, 176 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr8:71,197,433–73,370,601, 34 genes, copy number 12 (within-gene range 8–12): EYA1, TRAPPC2P2, AC009446.1, AC104012.1, U8, MSC-AS1, MSC, RPS20P20, TRPA1, AC078906.1, AC022905.1, RNA5SP271, AC124293.1, AC011131.1, KCNB2, HAUS1P3, AC013562.2, AC013562.1, AC090735.1, AC022893.2, TERF1, RNU6-285P, AC022893.3, AC022893.1, SBSPON, AC100823.1, AC100823.2, C8orf89, PRXL2AP2, RPL7, RDH10, RDH10-AS1, AC111149.1, AC111149.2.
- chr8:79,918,717–145,066,685, 1,040 genes, copy number 9–22 (within-gene range 8–22) (broad region; genes not listed).
- chr11:95,482,406–95,925,315, 8 genes, copy number 9 (within-gene range 6–9): AP001790.1, AP000820.2, AP000820.1, AP001877.1, FAM76B, CEP57, MTMR2, RNA5SP345.
- chr11:106,674,019–110,296,712, 50 genes, copy number 9 (within-gene range 6–9): GUCY1A2, AP001282.2, AP001282.1, ASS1P13, AP000766.1, CWF19L2, SMARCE1P1, ALKBH8, AP001823.1, ELMOD1, AP000889.2, AP000889.1, SLN, AP002353.1, SLC35F2, AP001024.1, RAB39A, AP003307.1, CUL5, Y_RNA, AP002433.1, ACAT1, AP002433.2, NPAT, ATM, Y_RNA, C11orf65, POGLUT3, EXPH5, DDX10, RPS2P39, AP002453.1, CYCSP29, AP003027.1, AP003123.1, RNU6-654P, RNA5SP349, SNORD39, AP003049.2, C11orf87, AP003049.1, AP003102.1, LINC02715, RDX, TFAMP2, AP001981.2, RPSAP50, AP001981.1, AP001889.1, ZC3H12C.
- chr16:70,802,084–71,230,722, 4 genes, copy number 10 (within-gene range 3–10): HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1.
- chr17:57,522,248–66,810,743, 302 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,018. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
